Somatic mutation profile of tumor specimen TCGA-EJ-7797-01A (aliquot TCGA-EJ-7797-01A-11D-2260-08) from TCGA case TCGA-EJ-7797, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 53.7 years (19,616 days).
Specimen TCGA-EJ-7797-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4bcece2f-f336-442a-ab2d-1d3f19fa9d89.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-7797-10A (Blood Derived Normal), aliquot TCGA-EJ-7797-10A-01D-2260-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/90741d0e-cc5e-4cc7-9bb4-8e2edfda3229

The open-access MAF lists 23 somatic variants for this specimen: 18 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 14, Silent 5, Nonsense Mutation 2, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.2152T>C p.F718L | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV64676253; called by muse, mutect2, varscan2
- ATOH1 | c.860T>A p.V287E | Missense Mutation (SNP) | VAF 7/134 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV60038449; called by muse, mutect2
- CNOT10 | c.1596-1G>C p.X532_splice | Splice Site (SNP) | VAF 22/663 reads (3%) | catalogued as COSV59394095; called by muse, mutect2
- DCAF4L2 | c.1112G>A p.R371H | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as rs747761232, COSV60479886; called by muse, mutect2, varscan2
- FAT3 | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.63); catalogued as COSV53154346; called by muse, mutect2
- FOXP1 | c.631C>T p.Q211* | Nonsense Mutation (SNP) | VAF 28/346 reads (8%) | catalogued as COSV59547627, COSV59549860, COSV59556517; called by muse, mutect2
- LAMA3 | c.7204C>T p.R2402* (on ENST00000313654 / NM_198129.4; = p.R793* on NM_000227.6) | Nonsense Mutation (SNP) | VAF 8/115 reads (7%) | catalogued as rs777713989, CM080430, COSV52540080; called by muse, mutect2
- NPHP4 | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 4/25 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.101); catalogued as rs761932891, COSV65396796; called by muse, mutect2, varscan2
- OR10J1 | c.697C>T p.R233W | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.072); catalogued as rs1016467615, COSV101419826, COSV71128897; called by muse, mutect2, varscan2
- POM121 | c.1364T>G p.I455R (on ENST00000434423; = p.I190R on NM_172020.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/140 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.006); catalogued as COSV57521591; called by muse, mutect2, varscan2
- PPM1K | c.1004C>T p.T335I | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); catalogued as COSV55797350; called by muse, mutect2, varscan2
- SERBP1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63413380; called by muse, mutect2, varscan2
- SLC12A4 | c.638C>G p.A213G | Missense Mutation (SNP) | VAF 6/111 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1346270178, COSV57933697; called by muse, mutect2
- TMX2 | c.526A>G p.I176V | Missense Mutation (SNP) | VAF 40/230 reads (17%) | SIFT tolerated (0.58); PolyPhen benign (0.007); catalogued as rs372453729; called by muse, mutect2, varscan2
- TTN | c.18952T>G p.S6318A (on ENST00000591111; = p.S5391A on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/280 reads (5%) | PolyPhen benign (0.009); catalogued as COSV60243797; called by muse, mutect2
- ZBTB6 | c.1028G>A p.R343Q | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65410482; called by muse, mutect2, varscan2
- EPHX2 | c.1221C>A p.S407R | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.891); called by muse, mutect2
- JAG2 | c.1678del p.C560Afs*26 | Frame Shift Del (DEL) | VAF 53/341 reads (16%) | called by mutect2, pindel, varscan2
- EVC | c.660C>T p.D220= | Silent (SNP) | VAF 72/414 reads (17%) | catalogued as rs200294295, COSV53836508; called by muse, mutect2, varscan2
- FAT4 | c.4494C>G p.A1498= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV67895521; called by muse, mutect2, varscan2
- FOXP1 | c.630G>T p.G210= | Silent (SNP) | VAF 29/342 reads (8%) | catalogued as COSV59549881; called by muse, mutect2
- NUTM1 | c.2118C>A p.S706= | Silent (SNP) | VAF 12/55 reads (22%) | catalogued as rs748446311, COSV59218222; called by muse, mutect2, varscan2
- SPATA31D1 | c.1845T>C p.S615= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV61199360; called by muse, mutect2
